Gene-level copy-number profile of tumor specimen ALCH-AFJR-TTP1-A from ALCHEMIST case ALCH-AFJR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.7 years (30,208 days).
Specimen ALCH-AFJR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38587d02-b749-48ff-ad9d-632a1a20908b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFJR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/e838e79c-fd31-45cc-bf3e-0c6cca88a531

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 508; copy number 1: 20,037; copy number 2: 34,152; copy number 3: 3,338; copy number 4: 360; copy number 5: 110; copy number 6: 80; copy number 7: 179; copy number 8: 31; copy number 9: 89; copy number 10: 16; copy number 11: 4; copy number 12: 6; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,356,136–12,359,391, 1 gene: ZNF705CP.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 517 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,151–2,184,820, 74 genes, copy number 7–11 (within-gene range 1–11) (broad region; genes not listed).
- chr5:3,595,832–6,600,288, 36 genes, copy number 5–6 (within-gene range 2–6): IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, UBE2QL1, AC027334.1, LINC01018.
- chr5:16,615,926–16,681,905, 1 gene, copy number 6 (within-gene range 1–6): AC024588.1.
- chr5:16,661,907–18,236,196, 52 genes, copy number 6: MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81.
- chr5:23,013,048–23,528,093, 7 genes, copy number 5: AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr5:31,053,565–32,110,932, 26 genes, copy number 7–12 (within-gene range 3–12): RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279.
- chr5:32,354,350–34,244,796, 32 genes, copy number 9: ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1.
- chr5:37,379,285–37,753,435, 3 genes, copy number 8 (within-gene range 2–8): WDR70, KCTD9P5, RNU6-1190P.
- chr5:50,662,859–50,934,521, 5 genes, copy number 5: AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2.
- chr5:52,008,031–52,581,106, 3 genes, copy number 5: LINC02118, RPS17P11, MFSD4BP1.
- chr8:12,310,962–12,318,316, 1 gene, copy number 9: DEFB130A.
- chr8:105,826,570–105,929,238, 2 genes, copy number 5: AC090802.1, Y_RNA.
- chr8:123,319,850–128,564,679, 94 genes, copy number 6–13 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:48,623,422–49,350,504, 13 genes, copy number 5 (within-gene range 1–5): AC007611.1, AC023813.3, AC023813.4, KLF8P1, RNU6-257P, AC023827.1, MTND4LP25, AC044798.3, AC044798.1, AC044798.2, CBLN1, AC007614.1, AC007614.2.
- chr16:51,755,325–53,329,150, 25 genes, copy number 9 (within-gene range 1–9): LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1, PHBP21, AC007346.1, AC007346.2, AC007906.2, CHD9, AC007906.1, AC079416.4, AC079416.2.
- chr16:65,284,496–66,801,620, 30 genes, copy number 7–12 (within-gene range 1–12): LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, CDH5, LINC00920, BEAN1, AC132186.1, BEAN1-AS1, AC010542.3, TK2, AC010542.2, AC010542.4, Y_RNA, CKLF, CKLF-CMTM1, AC010542.5, CMTM1, CMTM2, AC010542.1, CMTM3, CMTM4, DYNC1LI2, AC018557.1, AC018557.3, AC018557.2, AC044802.1, TERB1.
- chr16:68,084,751–68,229,259, 1 gene, copy number 9 (within-gene range 1–9): NFATC3.
- chr16:68,189,287–68,310,946, 16 genes, copy number 9: AC130462.1, AC020978.6, AC020978.8, RPS12P27, AC020978.3, AC020978.7, AC020978.5, ESRP2, MIR6773, AC020978.4, PLA2G15, AC020978.2, SLC7A6, RNU6-1262P, SLC7A6OS, AC020978.9.
- chr18:46,077,004–46,463,140, 8 genes, copy number 5: RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1.
- chr18:48,475,487–48,479,228, 3 genes, copy number 5: RNA5SP456, AC024288.1, POLR3GP2.
- chr20:6,006,093–7,258,323, 14 genes, copy number 9: CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2, AL096799.1, LINC01428, AL080248.1.
- chr20:9,505,180–11,029,455, 31 genes, copy number 5–7: LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1.
- chr20:12,243,308–13,784,886, 16 genes, copy number 5: AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1.
- chr20:21,395,365–22,074,654, 17 genes, copy number 7: NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432.
- chr22:18,110,331–18,177,397, 3 genes, copy number 7 (within-gene range 2–7): TUBA8, AC008079.1, USP18.

Autosomal genes at a single copy (total copy number 1): 17,694. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
